Gene-level copy-number profile of tumor specimen TCGA-2G-AAHP-05A from TCGA case TCGA-2G-AAHP, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.9 years (11,649 days).
Specimen TCGA-2G-AAHP-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.3f6c8076-0de7-4d47-90c2-f8df87018f2f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAHP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 432 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be624e60-6324-4885-b9ac-338d83c4aa1b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,179; copy number 1: 13; copy number 2: 5,989; copy number 3: 25,531; copy number 4: 9,508; copy number 5: 11,862; copy number 6: 3,997; copy number 7: 862; copy number 8: 9; copy number 9: 44; copy number 13: 195; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAHP-05A-11D-A42X-01): tumor purity 0.42, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,816,909–161,821,908, 1 gene: AC131211.1.
- chr9:60,914,407–61,662,690, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:5,761,153–5,783,355, 2 genes (within-gene range 0–3): OR56B2P, OR52N5.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr13:68,693,804–68,694,081, 1 gene: RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,112 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:129,990,456–130,509,707, 44 genes, copy number 9 (within-gene range 5–9): AC079776.4, AC079776.2, AC079776.1, ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9, CCDC74B, SMPD4, MZT2B, TUBA3E, AC018804.1, RHOQP3, NOC2LP1, AC134915.1, MED15P5, MTND1P29, MTND2P22, MTCO1P7, MTCO2P7, MTATP6P7, MTCO3P7, MTND3P15, AC068137.1, MTND4P27, MTND5P29, MTND6P8, MTCYBP8, RPL19P4, TEKT4P3, AC132479.1, CCDC115, IMP4, PTPN18, FAR2P2, KLF2P2, CYP4F62P, POTEI.
- chr8:8,228,595–8,244,865, 2 genes, copy number 14 (within-gene range 6–14): FAM86B3P, ALG1L13P.
- chr8:17,469,518–17,644,071, 9 genes, copy number 8 (within-gene range 6–8): ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5.
- chr10:93,881,293–93,961,540, 3 genes, copy number 7: RAB11AP1, SLC35G1, PIPSL.
- chr12:66,767–9,658,392, 343 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr12:9,594,551–38,274,549, 516 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–19,936,757, 82 genes, copy number 13 (broad region; genes not listed).
- chr14:105,785,505–106,436,555, 113 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
